Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A42H, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A42H-01A (Primary Tumor).

Addendum

MOLECULAR ANATOMIC PATHOLOGY TESTING:

Block 1G:

BRAF mutation NOT identified.

NOTE:

The quantity and quality of the isolated DNA was acceptable for testing.

BACKGROUND:

Mutations in the *BRAF* gene are found in ~50-60% of melanomas with *BRAF* V600E as the most common mutation type (90%) followed by V600K, V600D, and V600R (1,2). Rarely, mutations are identified in other codons of the *BRAF* gene, including codon 601 (K601E mutation) (3). Targeted therapy using selective *BRAF* inhibitors (i.e. PLX4032) may be effective in cases with *BRAF* mutations (4-6). However, not all tumors reveal such correlation and, therefore, the results of mutational testing should be interpreted in the context of the histologic findings and the patient's clinical history.

1. Fecher LA et al. Toward a molecular classification of melanoma. *J Clin Oncol*. 2007 20;25(12):1606-20.
2. Willmore-Payne et al. Human malignant melanoma: detection of *BRAF*- and *c-kit* activating mutations by high-resolution amplicon melting analysis. *Hum Pathol* 2005 36:486-93.
3. Ellerhorst et al. Clinical correlates of *NRAS* and *BRAF* mutations in primary human melanoma. *Clin Cancer Res* 2010 October 25.
4. Smalley KS et al. Genetic subgrouping of melanoma reveals new opportunities for targeted therapy. *Cancer Res* 2009 69:3241-4.
5. Sondak et al. Targeting mutant *BRAF* and *KIT* in metastatic melanoma: ASCO 2009 meeting report. *Pigment Cell Melanoma Res* 2009, 22:386-387.
6. Yang H, et al. RG7204 (PLX4032), a Selective *BRAF*V600E Inhibitor, Displays Potent Antitumor Activity in Preclinical Melanoma Models. *Cancer Res*. 2010 Jun 15. [Epub ahead of print].

BRAF MUTATIONAL ANALYSIS:

For surgical specimens, manual microdissection was performed. Specimens with the minimum of 50% of tumor cells in a microdissection target are accepted for the analysis. DNA was isolated using standard laboratory procedure. Optical density readings were obtained. For the detection of mutation, DNA was amplified with primers flanking *BRAF* exon 15 sequence. The quality of amplified PCR product was evaluated by agarose gel electrophoresis. Then, bidirectional Sanger sequencing was performed using the BigDye Terminator Kit on ABI3130. The known hotspots were analyzed for the presence of mutations with Mutation Surveyor V3.01. The limit of detection is approximately 20% of mutant alleles present in the background of normal DNA.

FINAL DIAGNOSIS:

- PARTS 1-3: COLON, RECTOSIGMOID COLON, ABDOMINAL PERITONEAL RESECTION -**
- A. MALIGNANT MELANOMA, 7.0 CM, INVOLVING THE ANAL RECTAL JUNCTION WITH SURFACE ULCERATION EXTENDING INTO SKELETAL MUSCLE (see comment).
- B. LYMPHOVASCULAR INVASION IS PRESENT.
- C. NO PERINEURAL INVASION IS PRESENT.
- D. SURGICAL MARGINS OF RESECTION, NEGATIVE FOR MALIGNANCY (see comment).
- E. METASTATIC MELANOMA INVOLVING SEVEN OUT OF SEVENTEEN LYMPH NODES (7/17).
- F. COLONIC MUCOSA IS HISTOLOGICALLY UNREMARKABLE.
- G. ATROPHIC SEMINAL VESICLES.

PART 6: SIGMOID COLON, SEGMENTAL RESECTION -

- A. DIVERTICULOSIS WITH ACUTE ORGANIZING SEROSITIS.
- B. FIVE LYMPH NODES, NEGATIVE FOR MELANOMA AND CARCINOMA (0/5).

COMMENT:

The tumor measures 7.0 cm in greatest diameter and extends into the skeletal muscle. Given the lentiginous spread in the anal mucosa, this is most likely a primary lesion of the anorectal region. *BRAF* mutation analysis can be performed if clinically indicated.

There is no AJCC staging criteria for anorectal melanoma, therefore no synoptic was filled out. If this lesion was staged as a skin melanoma, the stage would be pT4N3.

There is cauterized tumor on the primary specimen less than 1 mm from the anterior margin, however an additional anterior margin was submitted. Immunohistochemical stains for S100 showed a normal pattern of nerves and along with HMB45 and MelanA are negative for melanoma. Therefore, the final margins of resection are negative for malignancy.

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, in situ hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the required by the CLIA '88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Metastatic anorectal melanoma.

PROCEDURE: AP resection.

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMOTHERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

Source: NCI Genomic Data Commons file be4a8e89-738d-4e80-9368-0b8330782eae (TCGA-ER-A42H.A0ED997A-DE1F-4339-B149-9B0C2A8FF8EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).